Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3H7, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3H7-01A (Primary Tumor).

[page 1 of 2]
Primary Tumor Size Discrepancy		☒

ry Case gy Report

Pathology,
Fax:

DOB:
Physician:

Sex: F

Received:

Pathologist:

Accession:

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) DELPHIAN LYMPH NODE:
METASTATIC PAPILLARY CARCINOMA IN ONE LYMPH NODE.
- (B) RULE OUT PARATHYROID:
Thyroid tissue with chronic inflammation.
- (C) THYROID:
PAPILLARY CARCINOMA OF THYROID WITH EXTRATHYROIDAL INVASION INTO
SOFT TISSUE.
TUMOR IS AT CAUTERIZED EDGE.
Chronic thyroiditis.
- (D) NODE ON RECURRENT NERVE:
METASTATIC PAPILLARY CARCINOMA IN ONE LYMPH NODE.
No extracapsular extension.
- (E) PARATHYROID #2:
Parathyroid tissue, no tumor.
- (F) PARATRACHEAL NODES:
METASTATIC PAPILLARY CARCINOMA IN 6 OF 7 LYMPH NODES.

100-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9 W

11/30/11

Entire report and diagnosis completed by:
Report released by:

GROSS DESCRIPTION

- (A) DELPHIAN LYMPH NODE - A single lymph node (0.4 x 0.4 x 0.3 cm). The specimen is bisected and entirely submitted in A.
- (B) RULE OUT PARATHYROID CANCER - A pink-red fragment of soft tissue, 0.2 x 0.1 x 0.1 cm. The specimen is entirely submitted for frozen section in B.

*FS/DX: THYROID TISSUE. IF ORIGIN IS LYMPH NODE, TISSUE REPRESENTS A METASTASIS. NO LYMPH NODE STRUCTURE IDENTIFIED.

(C) THYROID - A thyroid, 4.0 x 2.5 x 1.5 cm. Two separate nodules are present within the thyroid. The larger nodule (3.0 x 2.6 x 1.7 cm) is present in the midportion of the right thyroid. The tumor abuts the thyroid capsule, but does not grossly invade through the capsule. A small amount of skeletal muscle is present on the outer surface of the thyroid capsule. The cut surface of the tumor is tan-brown, homogenous, and nodular. A separate nodule (0.8 x 0.7 x 0.6 cm) is present in the lower portion of the left thyroid. The nodule has a tan, glistening cut surface and is slightly more firm than the first described nodule. The remainder of the thyroid is unremarkable.

SECTION CODE: C1-C6, right lobe of thyroid submitted from superior (C1) to inferior (C6); C7-C10, entire left lobe of thyroid submitted from superior (C7) to (C10); C11-C14, remainder of right thyroid and nodule submitted from

[page 2 of 2]
History Case Pathology Report

Department of Pathology,

Tel: Fax

DOB:

Sex: F

Physician:

Received:

Pathologist:

Accession:

Case type: Surgical History

superior (C11) to inferior (C14).

A portion of the specimen was submitted to the tumor bank by Dr.

(D) NODE ON RECURRENT NERVE - A lymph node, (0.4 x 0.3 x 0.3 cm). The lymph node is bisected and entirely submitted in D.

(E) RULE OUT PARATHYROID #2 - A pink fragment of soft tissue, 0.2 x 0.2 x 0.1 cm. One touch prep is performed. The specimen is entirely submitted for frozen section in E.

*FS/DX: PARATHYROID TISSUE.

(F) PARATRACHEAL NODES - Multiple lymph nodes ranging from 0.3 to 0.6 cm in greatest dimension.

SECTION CODE: F1-F3, multiple possible lymph nodes per cassette.

SNOMED CODES

M-80503 M-80506 T-86000 T-C4200

Source: NCI Genomic Data Commons file 5b8540c1-56b4-4662-9a94-0cf583113c43 (TCGA-EL-A3H7.B0A349A2-09BE-4A7C-A4BD-C0EBAA9B33D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).